Somatic mutation profile of tumor specimen TCGA-CV-7432-01A (aliquot TCGA-CV-7432-01A-11D-2129-08) from TCGA case TCGA-CV-7432, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 79.1 years (28,875 days).
Specimen TCGA-CV-7432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82169d76-63a2-43fd-aeee-71ddc7670661.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7432-10A (Blood Derived Normal), aliquot TCGA-CV-7432-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e845045f-72cf-4e90-9ce1-2a96a8efea02

The open-access MAF lists 166 somatic variants for this specimen: 122 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 39, Frame Shift Del 9, Nonsense Mutation 8, RNA 2, 3'UTR 2, Splice Region 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274808359, CM994189, COSV58820033; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 24/86 reads (28%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4585G>C p.E1529Q | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52200641; called by muse, mutect2, varscan2
- ABCB1 | c.3521C>T p.T1174I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99714414; called by muse, mutect2, varscan2
- ABRA | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV61733768; called by muse, mutect2, varscan2
- ACSM2B | c.1470G>T p.E490D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100312624, COSV100313144; called by muse, mutect2, varscan2
- ADCY2 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV100604131, COSV57860132; called by muse, mutect2, varscan2
- ADGRL3 | c.1410T>A p.H470Q (on ENST00000506720 / NM_001322402.2; = p.H402Q on NM_015236.6) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.07); catalogued as COSV101547392; called by muse, mutect2, varscan2
- AGMO | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100694726; called by muse, mutect2, varscan2
- AJUBA | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99401200; called by muse, mutect2, varscan2
- ANAPC1 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV100595095; called by muse, mutect2, varscan2
- ANKRD12 | c.3536C>G p.S1179C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.315); catalogued as COSV100042100, COSV50820822; called by muse, mutect2, varscan2
- ARAP2 | c.3766A>G p.I1256V | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV100395258; called by muse, mutect2, varscan2
- ASXL1 | c.1633del p.R545Vfs*158 | Frame Shift Del (DEL) | VAF 43/167 reads (26%) | catalogued as COSV60103590; called by mutect2, pindel, varscan2
- ATP2A3 | c.613A>G p.K205E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.821); catalogued as rs1030754452, COSV99989675; called by muse, mutect2, varscan2
- BRDT | c.2135A>G p.D712G | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV100746590; called by muse, mutect2, varscan2
- BTG3 | c.422A>T p.D141V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100336382, COSV60286407; called by muse, mutect2, varscan2
- C1orf87 | c.813A>T p.K271N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as COSV100967254; called by muse, mutect2, varscan2
- CACNA1I | c.4910G>T p.G1637V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361545; called by muse, varscan2
- CCDC198 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV99371396; called by muse, mutect2, varscan2
- CDH8 | c.2042A>T p.D681V | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100182986, COSV100184178; called by muse, mutect2, varscan2
- CFAP53 | c.968A>T p.E323V | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV101275035; called by muse, mutect2, varscan2
- CFAP65 | c.3088C>A p.L1030M | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100445937; called by muse, mutect2, varscan2
- CFTR | c.2602G>A p.V868I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as CX972736, COSV99139797; called by muse, mutect2, varscan2
- CHRM2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs1409906654, COSV57768248; called by muse, mutect2, varscan2
- CSMD1 | c.9485C>T p.P3162L (on ENST00000520002; = p.P3161L on NM_033225.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1251288122, COSV100151714, COSV100153736; called by muse, mutect2, varscan2
- CST11 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs758922528, COSV100776874; called by muse, mutect2, varscan2
- CTNND2 | c.2790C>A p.G930= | Splice Region (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100481077; called by muse, mutect2, varscan2
- CYFIP2 | c.266G>C p.C89S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100557774; called by muse, mutect2, varscan2
- CYFIP2 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100557777; called by muse, mutect2, varscan2
- CYSLTR2 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs201906229, COSV99935070, COSV99935404; called by muse, mutect2, varscan2
- DBF4B | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100154720; called by muse, mutect2, varscan2
- DOCK2 | c.3562T>A p.Y1188N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99915442; called by muse, mutect2, varscan2
- DOP1A | c.648A>T p.Q216H | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99382933; called by muse, mutect2, varscan2
- DPP10 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100071754; called by muse, mutect2, varscan2
- DYNC1I1 | c.176C>G p.T59R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as COSV100269279; called by muse, mutect2, varscan2
- DYNC2H1 | c.11364G>C p.W3788C | Missense Mutation (SNP) | VAF 25/805 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519747; called by muse, mutect2
- EEF1AKMT3 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV99141563, COSV99141657; called by muse, varscan2
- EPHA3 | c.882T>G p.S294R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100348779; called by muse, mutect2, varscan2
- FAF2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1048151912, COSV99990689; called by muse, mutect2, varscan2
- FAM102A | c.960C>A p.D320E (on ENST00000373095 / NM_001035254.3; = p.D178E on NM_203305.2) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.297); catalogued as COSV100305631; called by mutect2, varscan2
- FAM47C | c.1702T>C p.Y568H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.106); catalogued as COSV100792946; called by muse, varscan2
- FBN2 | c.5904T>G p.N1968K | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99330669; called by muse, mutect2, varscan2
- FLRT2 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs1235321299, COSV100420697; called by muse, mutect2, varscan2
- GABBR2 | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV52296908, COSV99411553; called by muse, mutect2, varscan2
- GALNT13 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs751205543, COSV67222006; called by muse, mutect2, varscan2
- GALNT8 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1177058405, COSV99363252; called by muse, mutect2, varscan2
- GBA3 | c.887T>C p.M296T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1055501573, COSV101545572; called by muse, mutect2, varscan2
- GGTLC2 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV101312264; called by muse, mutect2, varscan2
- GJA10 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV101005446, COSV65356549; called by muse, mutect2, varscan2
- GMPS | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV99903408; called by muse, mutect2
- GNL3L | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV60575392; called by muse, varscan2
- GUCY1A1 | c.1773G>A p.M591I | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1382479789, COSV99638695; called by muse, varscan2
- KCNE3 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1252788225, COSV100035699; called by muse, mutect2, varscan2
- KCNH3 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs758173591, COSV99235801; called by muse, mutect2, varscan2
- KHDC4 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.404); catalogued as COSV100850855; called by muse, mutect2, varscan2
- KRT5 | c.1481T>A p.V494D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99358275; called by muse, mutect2, varscan2
- KRTAP13-2 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV101299673; called by muse, mutect2, varscan2
- LDHD | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100097576; called by muse, mutect2, varscan2
- LIFR | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs912734748, COSV99665521; called by muse, mutect2, varscan2
- LILRA2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.251); catalogued as COSV99253951; called by muse, mutect2, varscan2
- LINS1 | c.470A>C p.Y157S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100130559; called by muse, mutect2, varscan2
- LRP1B | c.2269A>C p.M757L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV101255544, COSV101261069; called by muse, mutect2, varscan2
- LRRK2 | c.6851del p.G2284Efs*5 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as COSV100110281; called by mutect2, varscan2
- MAP1S | c.2915G>T p.R972L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100141246; called by muse, mutect2, varscan2
- MCF2 | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100645159; called by muse, mutect2, varscan2
- MPP6 | c.961C>A p.R321S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV99757858, COSV99757912; called by mutect2, varscan2
- MXRA5 | c.5210C>T p.T1737I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99479274; called by muse, mutect2, varscan2
- MYLK2 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs755753841, COSV101044948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECAB1 | c.407T>A p.L136* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV101341214; called by muse, mutect2, varscan2
- NLRP4 | c.1559G>T p.G520V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100017185; called by muse, mutect2, varscan2
- NLRP7 | c.1544T>A p.L515Q | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053377; called by muse, mutect2, varscan2
- NMBR | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV99237531; called by muse, mutect2, varscan2
- NRXN3 | c.1796C>T p.T599M (on ENST00000557594 / NM_001272020.2; = p.T1023M on NM_004796.6) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs369782422; called by muse, mutect2, varscan2
- OAS2 | c.755T>A p.L252Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100660321; called by muse, mutect2, varscan2
- OR10K1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV99193255; called by muse, mutect2, varscan2
- OR5D14 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.344); catalogued as rs149902192, COSV59457590; called by muse, mutect2, varscan2
- OR5D18 | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV100450900, COSV61737635; called by muse, mutect2, varscan2
- OTULINL | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99947150, COSV99947369; called by muse, mutect2, varscan2
- PCDHB14 | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs782313425, COSV99506289; called by muse, mutect2, varscan2
- PCDHB3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50564990; called by muse, mutect2, varscan2
- PCYT1A | c.726G>T p.L242F | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99492454; called by muse, mutect2, varscan2
- PGK2 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 33/122 reads (27%) | catalogued as COSV100505695; called by muse, mutect2, varscan2
- PI16 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV65448025; called by muse, mutect2, varscan2
- PIGN | c.2605G>T p.D869Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716220; called by muse, mutect2, varscan2
- PLA1A | c.1019A>T p.H340L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99846077; called by muse, mutect2, varscan2
- POSTN | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV65712152; called by muse, mutect2, varscan2
- PPP2R2D | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101409008; called by muse, mutect2, varscan2
- PTGIS | c.1457T>C p.M486T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99721302; called by muse, mutect2, varscan2
- PTK2 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100571235; called by muse, mutect2, varscan2
- PTOV1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV99682024; called by muse, mutect2, varscan2
- PTPRG | c.2923A>G p.N975D | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV99876928; called by muse, mutect2, varscan2
- RGS7 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV100470950; called by muse, varscan2
- RYR2 | c.14474G>A p.G4825E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772902, COSV63657518; called by muse, mutect2, varscan2
- SCGN | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143515197; called by muse, mutect2, varscan2
- SCN1A | c.4570C>A p.P1524T (on ENST00000303395 / NM_001202435.3; = p.P1513T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143088184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFTPD | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100954570; called by muse, mutect2, varscan2
- SLC41A1 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100900500; called by muse, mutect2, varscan2
- SLC45A2 | c.437T>G p.M146R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99673127; called by muse, mutect2, varscan2
- SLCO1B1 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1281002838, COSV99919146; called by muse, mutect2, varscan2
- SPAG6 | c.796T>A p.Y266N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100510490; called by muse, mutect2, varscan2
- STK32B | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.14); catalogued as COSV99287375; called by muse, mutect2, varscan2
- SYNE1 | c.1927A>T p.K643* (on ENST00000367255 / NM_182961.4; = p.K650* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 36/128 reads (28%) | catalogued as COSV55080601, COSV99578779; called by muse, mutect2, varscan2
- THSD7A | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101448904; called by muse, mutect2, varscan2
- TNN | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs17374761; called by muse, mutect2, varscan2
- TTC37 | c.2387C>T p.T796I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV100706892; called by muse, mutect2, varscan2
- TTN | c.21476T>C p.L7159S (on ENST00000591111; = p.L6232S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | PolyPhen probably damaging (0.999); catalogued as COSV100630193; called by muse, mutect2, varscan2
- UTRN | c.5809G>T p.E1937* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV100840644; called by muse, mutect2, varscan2
- VCAN | c.3439A>G p.T1147A | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV99427332; called by muse, mutect2, varscan2
- ZFHX3 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV99214695; called by muse, mutect2, varscan2
- ZNF33B | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100847781; called by muse, mutect2, varscan2
- ZNF626 | c.1234C>A p.L412I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV101657013; called by muse, mutect2, varscan2
- ZNF652 | c.650T>G p.V217G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100755689; called by muse, mutect2, varscan2
- ZNF700 | c.1228A>G p.R410G | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866635709, COSV99583811; called by muse, mutect2, varscan2
- GPR157 | c.326_345del p.V109Afs*33 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- ITFG2 | c.323_325delinsGG p.E108Gfs*3 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | called by pindel, varscan2*
- RAPGEF6 | c.357dup p.N120Efs*5 | Frame Shift Ins (INS) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- SIGLEC1 | c.954del p.I319Sfs*12 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- TLK1 | c.2063_2069del p.T688Kfs*10 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- TP53 | c.717_727del p.S240Gfs*20 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- TTN | c.54418_54419delinsA p.L18140Mfs*6 (on ENST00000591111; = p.L10716Mfs*6 on NM_003319.4) | Frame Shift Del (DEL) | VAF 54/167 reads (32%) | called by pindel, varscan2*
- ZNF623 | c.216del p.S73Lfs*9 | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- ALDH1A1 | c.882G>A p.G294= | Silent (SNP) | VAF 64/180 reads (36%) | catalogued as COSV99921656; called by muse, mutect2, varscan2
- ASPHD2 | c.615C>T p.L205= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV53218881; called by muse, mutect2, varscan2
- BARHL1 | c.591C>T p.F197= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99707714; called by muse, mutect2, varscan2
- BTBD2 | c.597G>A p.K199= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99724970; called by muse, mutect2, varscan2
- CDH6 | c.1398A>G p.P466= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99420844; called by muse, mutect2, varscan2
- CDKL5 | c.738G>T p.G246= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as COSV101184453; called by muse, mutect2, varscan2
- CDX1 | c.576G>A p.G192= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs1032049779, COSV99199342; called by muse, mutect2, varscan2
- COL4A3 | c.2817A>G p.K939= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100516865; called by muse, mutect2, varscan2
- CST5 | c.147C>T p.D49= | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as COSV100489748; called by muse, mutect2, varscan2
- CUBN | c.7692C>A p.S2564= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100912160; called by muse, mutect2, varscan2
- DIAPH3 | c.2349T>A p.P783= (on ENST00000400324 / NM_001042517.2; = p.P520= on NM_030932.3) | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV99934499; called by muse, mutect2, varscan2
- ENO2 | c.816T>A p.T272= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV99980483; called by muse, mutect2, varscan2
- FOXD4L1 | c.834C>A p.A278= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV99380822; called by muse, mutect2, varscan2
- FXR2 | c.1749A>G p.Q583= | Silent (SNP) | VAF 58/200 reads (29%) | catalogued as rs561587687, COSV100002235; called by muse, mutect2, varscan2
- HTR1A | c.1080C>T p.P360= | Silent (SNP) | VAF 36/172 reads (21%) | catalogued as COSV100109287; called by muse, mutect2, varscan2
- ILKAP | c.802C>A p.R268= | Silent (SNP) | VAF 89/296 reads (30%) | catalogued as COSV99610990, COSV99611167; called by muse, mutect2, varscan2
- KIAA0825 | c.354T>G p.L118= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100266087; called by muse, mutect2, varscan2
- LRRC1 | c.1533C>T p.N511= | Silent (SNP) | VAF 47/307 reads (15%) | catalogued as rs776526801, COSV100906364; called by muse, mutect2, varscan2
- LRRC30 | c.297G>A p.L99= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101274457; called by muse, mutect2, varscan2
- MAPKAP1 | c.1416T>C p.A472= (on ENST00000265960 / NM_001006617.3; = p.A436= on NM_024117.3) | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as COSV99785717; called by muse, mutect2, varscan2
- MIA | c.195C>T p.H65= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs1407532101, COSV99648303; called by muse, mutect2, varscan2
- MYH4 | c.318C>T p.L106= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as COSV99702243; called by muse, mutect2, varscan2
- MYLK | c.57G>A p.V19= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100659628; called by muse, mutect2, varscan2
- MYOM2 | c.1215G>A p.P405= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs563008335, COSV50754142; called by muse, mutect2, varscan2
- NUP210 | c.4182G>A p.V1394= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV99597040; called by muse, mutect2, varscan2
- PCDHA13 | c.276C>T p.R92= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as COSV56493766; called by muse, mutect2
- PCDHB11 | c.1350C>A p.T450= | Silent (SNP) | VAF 75/240 reads (31%) | catalogued as COSV100697177; called by muse, mutect2, varscan2
- PCSK1 | c.909C>T p.F303= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV60733876; called by muse, mutect2
- PDHA2 | c.753G>A p.K251= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV54780729, COSV99757314; called by muse, mutect2, varscan2
- REG3G | c.402G>A p.E134= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV99709710; called by muse, mutect2, varscan2
- REV3L | c.4107A>G p.A1369= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs537030557, COSV100725687; called by muse, mutect2, varscan2
- SIPA1L1 | c.72C>T p.D24= | Silent (SNP) | VAF 49/145 reads (34%) | catalogued as rs112129340; called by muse, mutect2, varscan2
- SLIT3 | c.3039C>T p.D1013= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs79266600; called by muse, mutect2, varscan2
- SNRPB2 | c.39T>C p.N13= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV99855912; called by muse, mutect2, varscan2
- SURF4 | c.87G>A p.A29= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs1261762529, COSV64339106; called by muse, mutect2, varscan2
- TBC1D25 | c.2022G>A p.E674= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs1466458007, COSV100952234; called by muse, mutect2, varscan2
- TSPYL5 | c.18G>T p.R6= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100439127; called by muse, mutect2, varscan2
- TTC5 | c.276G>T p.L92= | Silent (SNP) | VAF 67/135 reads (50%) | catalogued as COSV51872505; called by muse, mutect2, varscan2
- ZNF709 | c.1437A>G p.K479= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs1255043924, COSV101172301; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1144C>T | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs375468459; called by muse, mutect2, varscan2
- MFSD4B | c.*1C>A | 3'UTR (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100920615; called by muse, mutect2
- NBPF7 | n.73A>T | RNA (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- SSPOP | n.7187G>A | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100023004; called by muse, mutect2
- XIRP2 | c.*671A>C | 3'UTR (SNP) | VAF 15/49 reads (31%) | catalogued as rs777715200, COSV99747451; called by muse, mutect2, varscan2
